Somatic mutation profile of tumor specimen TCGA-XU-AAXY-01A (aliquot TCGA-XU-AAXY-01A-11D-A428-09) from TCGA case TCGA-XU-AAXY, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 43.1 years (15,756 days).
Specimen TCGA-XU-AAXY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23e774c7-fb4c-4a85-9964-7f959023e371.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-AAXY-10A (Blood Derived Normal), aliquot TCGA-XU-AAXY-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29fa619a-81b2-45c8-81eb-161ae4ef1155

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP2 | c.695A>T p.Q232L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PKNOX1 | c.705G>T p.R235S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.185); called by muse, mutect2
- SLC12A4 | c.2687C>A p.A896D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.096); called by muse, mutect2
- CRIPT | c.6G>T p.V2= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- NOP53 | c.481C>T p.L161= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
